Somatic mutation profile of tumor specimen TCGA-61-2087-01A (aliquot TCGA-61-2087-01A-01W-0722-08) from TCGA case TCGA-61-2087, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IC; Tumor grade: G3; Age at diagnosis: 49.8 years (18,182 days).
Specimen TCGA-61-2087-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 13cd5346-b999-4982-9031-59cf9e853de2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-61-2087-11A (Solid Tissue Normal), aliquot TCGA-61-2087-11A-01W-0722-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0e61a71c-b214-4128-bf04-b6748b6f55a5

The open-access MAF lists 93 somatic variants for this specimen: 69 protein-altering or splice-affecting, 21 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 21, Frame Shift Del 5, Nonsense Mutation 3, Frame Shift Ins 3, Intron 1, 3'Flank 1, In Frame Del 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 86/90 reads (96%) | hotspot (GDC flag); catalogued as rs866380588, COSV52660737, COSV52978302; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADPRHL1 | c.333G>C p.K111N | Missense Mutation (SNP) | VAF 79/95 reads (83%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as COSV100733480; called by muse, mutect2, varscan2
- AKAP9 | c.2986G>A p.E996K | Missense Mutation (SNP) | VAF 92/346 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.906); catalogued as COSV100662673; called by muse, mutect2, varscan2
- ATG2B | c.5086C>A p.Q1696K | Missense Mutation (SNP) | VAF 49/166 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.3); catalogued as COSV99952140; called by muse, mutect2, varscan2
- ATP8B3 | c.821G>A p.G274E | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100034670; called by muse, varscan2
- BPTF | c.3508G>T p.G1170C | Missense Mutation (SNP) | VAF 28/34 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100075397; called by muse, mutect2, varscan2
- CHUK | c.1801C>T p.L601F | Missense Mutation (SNP) | VAF 74/180 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV100957193; called by muse, mutect2, varscan2
- CYP1A2 | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 152/426 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.212); catalogued as COSV100673914; called by muse, mutect2, varscan2
- DBH | c.1789C>G p.P597A | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.162); catalogued as COSV101257090; called by muse, mutect2, varscan2
- DISC1 | c.716G>T p.C239F | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV99698179; called by muse, mutect2, varscan2
- DNAH3 | c.5777-1G>A p.X1926_splice | Splice Site (SNP) | VAF 41/114 reads (36%) | catalogued as COSV99768916; called by muse, mutect2, varscan2
- DNAH5 | c.13798G>A p.A4600T | Missense Mutation (SNP) | VAF 144/445 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as rs774279588, COSV54241462; called by muse, mutect2, varscan2
- DNAJC21 | c.593A>G p.E198G | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100331511; called by muse, mutect2, varscan2
- DNAJC22 | c.258A>G p.I86M | Missense Mutation (SNP) | VAF 78/200 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as COSV67711517; called by muse, mutect2, varscan2
- DPP4 | c.2014G>T p.G672C | Missense Mutation (SNP) | VAF 60/82 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100858953; called by muse, mutect2, varscan2
- DPP4 | c.2013G>T p.M671I | Missense Mutation (SNP) | VAF 60/82 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100858954; called by muse, mutect2, varscan2
- FAF2 | c.1197A>T p.E399D | Missense Mutation (SNP) | VAF 146/417 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV99990564; called by muse, varscan2
- FAM47C | c.1559C>A p.S520Y | Missense Mutation (SNP) | VAF 58/122 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.729); catalogued as COSV100792793; called by muse, mutect2, varscan2
- FER1L6 | c.865C>T p.Q289* | Nonsense Mutation (SNP) | VAF 87/179 reads (49%) | catalogued as COSV101206048; called by muse, mutect2, varscan2
- FHOD3 | c.2343G>C p.K781N (on ENST00000359247 / NM_001281739.3; = p.K798N on NM_025135.5) | Missense Mutation (SNP) | VAF 95/257 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV99941886; called by muse, mutect2, varscan2
- GABRA5 | c.619A>G p.N207D | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.216); catalogued as COSV100165459; called by muse, mutect2
- GCNA | c.1852A>G p.R618G | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.671); catalogued as COSV101031677; called by muse, mutect2, varscan2
- GDI1 | c.1340A>C p.Q447P | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.276); catalogued as COSV99341108; called by muse, mutect2, varscan2
- HECTD1 | c.7789C>T p.R2597C | Missense Mutation (SNP) | VAF 64/152 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV67946225; called by muse, mutect2, varscan2
- HIVEP2 | c.2356A>C p.M786L | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV99174426; called by muse, mutect2, varscan2
- IKZF1 | c.260C>G p.A87G | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated (0.45); PolyPhen benign (0.123); catalogued as COSV100498561; called by muse, mutect2, varscan2
- LAMA4 | c.3557G>C p.R1186T (on ENST00000230538 / NM_001105206.3; = p.R1179T on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV100038864; called by muse, mutect2, varscan2
- NKAIN2 | c.254A>G p.E85G | Missense Mutation (SNP) | VAF 259/602 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.245); catalogued as COSV100863348; called by muse, mutect2, varscan2
- OR2T33 | c.601T>G p.C201G | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV100532135; called by muse, mutect2, varscan2
- OR2T6 | c.83del p.F28Sfs*12 | Frame Shift Del (DEL) | VAF 53/121 reads (44%) | catalogued as COSV63216616; called by mutect2, pindel, varscan2
- OR51E2 | c.560C>A p.A187D | Missense Mutation (SNP) | VAF 90/115 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as rs773992553, COSV101211370, COSV67807529; called by muse, mutect2, varscan2
- PADI6 | c.1150G>A p.D384N | Missense Mutation (SNP) | VAF 44/48 reads (92%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs560246479, COSV100639931; called by muse, mutect2, varscan2
- PCDH7 | c.2667G>A p.M889I | Missense Mutation (SNP) | VAF 50/54 reads (93%) | SIFT tolerated (0.5); PolyPhen benign (0.038); catalogued as COSV100688506; called by muse, mutect2, varscan2
- PKNOX2 | c.1370C>T p.T457M | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.446); catalogued as rs762099105, COSV53543136; called by muse, mutect2, varscan2
- PRDM4 | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 71/232 reads (31%) | SIFT tolerated (0.78); PolyPhen benign (0.006); catalogued as COSV57305416; called by muse, mutect2, varscan2
- PRDM7 | c.955G>T p.V319L | Missense Mutation (SNP) | VAF 66/153 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.591); catalogued as COSV100371282; called by muse, mutect2, varscan2
- ROBO2 | c.3224C>A p.P1075H | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV100168233; called by mutect2, varscan2
- RPL9 | c.490G>C p.A164P | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT tolerated (0.08); PolyPhen benign (0.254); catalogued as COSV99787769; called by muse, mutect2, varscan2
- RSBN1L | c.2218dup p.S740Ffs*3 | Frame Shift Ins (INS) | VAF 68/217 reads (31%) | catalogued as rs1266937203; called by mutect2, pindel, varscan2
- RYR2 | c.2134G>T p.E712* | Nonsense Mutation (SNP) | VAF 85/202 reads (42%) | catalogued as COSV100771858, COSV63699013, COSV63708402; called by muse, mutect2, varscan2
- SAPCD1 | c.396G>C p.E132D (on ENST00000425424; = p.E162D on NM_001039651.1) | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV100991904; called by muse, mutect2, varscan2
- SLC17A6 | c.460G>A p.V154I | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.277); catalogued as COSV54137512; called by mutect2, varscan2
- SLC45A4 | c.1404C>A p.H468Q (on ENST00000517878 / NM_001286646.2; = p.H417Q on NM_001080431.2) | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV99198955, COSV99199316; called by muse, mutect2, varscan2
- SLC4A3 | c.3108dup p.L1037Afs*35 | Frame Shift Ins (INS) | VAF 8/48 reads (17%) | catalogued as rs757961785; called by mutect2, varscan2
- SPRTN | c.900C>G p.I300M | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV99149913; called by muse, mutect2, varscan2
- SPTAN1 | c.5453C>T p.P1818L | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs561973288, COSV63987629; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- SRRM2 | c.3846G>C p.L1282F | Missense Mutation (SNP) | VAF 157/403 reads (39%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.147); catalogued as COSV100071109; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.3412G>T p.D1138Y | Missense Mutation (SNP) | VAF 152/191 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100562036, COSV100562139; called by muse, mutect2, varscan2
- TAF4B | c.1222G>A p.G408R | Missense Mutation (SNP) | VAF 54/154 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.36); catalogued as COSV99300597; called by muse, mutect2, varscan2
- TENT5A | c.804C>G p.F268L | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.089); catalogued as COSV100199062, COSV60787442; called by muse, mutect2, varscan2
- TLL2 | c.572C>G p.T191S | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100780356; called by muse, mutect2, varscan2
- TMEM134 | c.268T>A p.S90T | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.322); catalogued as COSV100339451; called by muse, mutect2, varscan2
- TRIM56 | c.2047T>G p.S683A | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.931); catalogued as COSV100047513; called by muse, mutect2, varscan2
- TRIOBP | c.6982C>G p.L2328V (on ENST00000644935 / NM_001039141.3; = p.L615V on NM_007032.5) | Missense Mutation (SNP) | VAF 49/70 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100730984; called by muse, mutect2, varscan2
- UNC119B | c.614A>G p.Y205C | Missense Mutation (SNP) | VAF 78/195 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749898426, COSV100763490; called by muse, mutect2, varscan2
- UROC1 | c.1483A>T p.I495F | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99331852; called by muse, mutect2, varscan2
- USP14 | c.1432C>G p.L478V | Missense Mutation (SNP) | VAF 75/139 reads (54%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.85); catalogued as COSV99863511; called by muse, mutect2, varscan2
- USP31 | c.2500A>G p.T834A | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV99565498; called by muse, mutect2, varscan2
- WDR17 | c.1106T>C p.F369S | Missense Mutation (SNP) | VAF 316/785 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99707935; called by muse, mutect2, varscan2
- WFDC2 | c.5C>T p.P2L | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.234); catalogued as COSV99463752; called by muse, mutect2, varscan2
- WIZ | c.3905C>T p.S1302F (on ENST00000673675 / NM_001371589.1; = p.S207F on NM_021241.3) | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV99653507; called by muse, mutect2, varscan2
- XXYLT1 | c.846dup p.E283Rfs*85 | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | catalogued as rs745401645; called by pindel, varscan2
- ZNF510 | c.1747C>T p.R583W | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.038); catalogued as rs765526190; called by muse, mutect2
- ATOH8 | c.703del p.A235Rfs*38 | Frame Shift Del (DEL) | VAF 9/17 reads (53%) | called by mutect2, pindel, varscan2
- CDH2 | c.2221_2222del p.M741Vfs*10 | Frame Shift Del (DEL) | VAF 60/168 reads (36%) | called by mutect2, pindel, varscan2
- LRP1B | c.8956_8968del p.Y2986Sfs*28 | Frame Shift Del (DEL) | VAF 80/120 reads (67%) | called by mutect2, pindel, varscan2
- PRAF2 | c.55_70del p.S19Lfs*46 | Frame Shift Del (DEL) | VAF 10/23 reads (43%) | called by mutect2, varscan2
- SCAPER | c.2666_2701del p.L889_P900del | In Frame Del (DEL) | VAF 6/35 reads (17%) | called by mutect2, pindel
- SDS | c.244C>A p.P82T | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ADAMTS2 | c.3414C>A p.T1138= | Silent (SNP) | VAF 87/238 reads (37%) | catalogued as rs777522306, COSV99283019; called by muse, mutect2, varscan2
- ALDH8A1 | c.754C>T p.L252= | Silent (SNP) | VAF 66/147 reads (45%) | catalogued as rs768610596, COSV55640464, COSV99664733, COSV99664862; called by muse, mutect2, varscan2
- ANLN | c.132T>G p.L44= | Silent (SNP) | VAF 90/203 reads (44%) | catalogued as COSV99732558; called by muse, mutect2, varscan2
- AP4M1 | c.144C>G p.V48= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as COSV100385051; called by muse, varscan2
- ATP2A2 | c.2919C>G p.S973= | Silent (SNP) | VAF 45/120 reads (38%) | catalogued as COSV100428764; called by muse, mutect2, varscan2
- C11orf68 | c.273G>C p.G91= (on ENST00000530188; = p.G132= on NM_031450.4) | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV100437130; called by muse, mutect2, varscan2
- CHRNA3 | c.963C>T p.I321= | Silent (SNP) | VAF 117/255 reads (46%) | catalogued as COSV100468426; called by muse, mutect2, varscan2
- CNR1 | c.771C>T p.C257= | Silent (SNP) | VAF 57/135 reads (42%) | catalogued as rs760873291, COSV100759268; called by muse, mutect2, varscan2
- CPLX4 | c.249C>G p.L83= | Silent (SNP) | VAF 71/196 reads (36%) | catalogued as COSV100231456; called by muse, mutect2, varscan2
- DNAH5 | c.4629C>T p.D1543= | Silent (SNP) | VAF 242/808 reads (30%) | catalogued as rs149049465; called by muse, varscan2
- HFM1 | c.3651C>A p.S1217= | Silent (SNP) | VAF 40/120 reads (33%) | catalogued as COSV99646336; called by muse, mutect2, varscan2
- INSR | c.1383C>G p.L461= | Silent (SNP) | VAF 234/285 reads (82%) | catalogued as COSV100251494; called by muse, mutect2, varscan2
- KCTD21 | c.123G>A p.R41= | Silent (SNP) | VAF 109/255 reads (43%) | catalogued as COSV100399721, COSV100399762; called by muse, mutect2, varscan2
- MMP8 | c.24A>T p.P8= | Silent (SNP) | VAF 80/255 reads (31%) | catalogued as COSV52633117, COSV99368636; called by muse, mutect2, varscan2
- NOL4 | c.1707T>C p.N569= | Silent (SNP) | VAF 255/572 reads (45%) | catalogued as COSV99307454; called by muse, mutect2, varscan2
- NUDT9 | c.66G>C p.V22= | Silent (SNP) | VAF 77/179 reads (43%) | catalogued as COSV100139285; called by muse, mutect2, varscan2
- RXRG | c.93A>G p.A31= | Silent (SNP) | VAF 23/55 reads (42%) | catalogued as COSV100717702; called by muse, mutect2, varscan2
- SENP1 | c.1455G>A p.K485= | Silent (SNP) | VAF 76/195 reads (39%) | catalogued as COSV50307556, COSV99137032; called by muse, mutect2, varscan2
- STX1A | c.423C>T p.Y141= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as rs148465382; called by muse, mutect2, varscan2
- SYBU | c.240C>T p.G80= (on ENST00000276646 / NM_001099754.2; = p.G79= on NM_017786.6) | Silent (SNP) | VAF 18/19 reads (95%) | catalogued as COSV99406413; called by muse, mutect2, varscan2
- TNNT2 | c.504A>G p.R168= | Silent (SNP) | VAF 52/195 reads (27%) | catalogued as COSV99372426; called by muse, mutect2, varscan2
- NELFE | c.146-45A>C | Intron (SNP) | VAF 95/266 reads (36%) | catalogued as COSV100952815; called by muse, varscan2
- RNU6-104P | chr8:43304703 T>G | 3'Flank (SNP) | VAF 43/77 reads (56%) | called by muse, varscan2
- XIST | n.7303G>A | RNA (SNP) | VAF 58/144 reads (40%) | called by muse, mutect2, varscan2
